Somatic mutation profile of tumor specimen 573048dd-2502-40e0-8e8c-c41bb8 (aliquot 573048dd-2502-40e0-8e8c-c41bb8_D6) from CPTAC case 01CO019, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen 573048dd-2502-40e0-8e8c-c41bb8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76275a6f-a133-4bbd-b69f-9072db3afe65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6e1e0cf0-0af1-4561-b8f4-056fcb (Blood Derived Normal), aliquot 6e1e0cf0-0af1-4561-b8f4-056fcb_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3ecebb4-ec9a-4e79-b7d1-68487b318c2c

The open-access MAF lists 96 somatic variants for this specimen: 69 protein-altering or splice-affecting, 19 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 19, Nonsense Mutation 6, 3'UTR 5, Frame Shift Del 3, RNA 2, Frame Shift Ins 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3730C>T p.Q1244* | Nonsense Mutation (SNP) | VAF 55/207 reads (27%) | catalogued as rs79122263, CM010756, COSV57329765; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 44/151 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCC6 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs761364455; called by muse, mutect2, varscan2
- ALS2CL | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 114/236 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758663520; called by muse, mutect2, varscan2
- ANO6 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 186/342 reads (54%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.887); catalogued as rs761048570, COSV57658152; called by muse, mutect2, varscan2
- APBA2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 118/204 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs1416887852, COSV68792476; called by muse, mutect2, varscan2
- ARHGAP15 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs759344166, COSV54509110, COSV54514150; called by muse, mutect2, varscan2
- CASR | c.1802G>A p.R601H (on ENST00000490131; = p.R678H on NM_000388.4) | Missense Mutation (SNP) | VAF 67/407 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs1278025825, CM165796, COSV56139931, COSV56142619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC88C | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 110/373 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs760958028, COSV66234490; called by muse, mutect2, varscan2
- CLK3 | c.1901G>A p.R634H (on ENST00000395066 / NM_001130028.1; = p.R486H on NM_003992.4) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as rs776802676; called by muse, mutect2, varscan2
- DIP2B | c.2461C>T p.R821* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as rs1261122361, COSV56582924; called by muse, mutect2, varscan2
- DLG2 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs200531656; called by muse, mutect2, varscan2
- DNER | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs143853534, COSV59180001; called by muse, mutect2, varscan2
- DRD2 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 133/440 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773041317, COSV60759202; called by muse, mutect2, varscan2
- DYRK1A | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100117318; called by muse, mutect2
- ERBB3 | c.655T>G p.F219V | Missense Mutation (SNP) | VAF 300/448 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57246260, COSV99918190; called by muse, mutect2, varscan2
- FLT1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755508412; called by muse, mutect2, varscan2
- GATA4 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs1430911633; called by muse, varscan2
- GDF5 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65501832; called by muse, mutect2, varscan2
- GPA33 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs373880766; called by muse, mutect2, varscan2
- HOXC12 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 74/124 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745967545; called by muse, mutect2, varscan2
- HOXC13 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54499256; called by muse, mutect2
- IMPG1 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 61/110 reads (55%) | catalogued as rs745936741, COSV64061510; called by muse, mutect2, varscan2
- KRI1 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.446); catalogued as rs746859306, COSV57264843; called by muse, mutect2, varscan2
- MAGEC3 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV68924432; called by muse, mutect2
- MDN1 | c.12187C>T p.R4063C | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs139837822; called by muse, mutect2, varscan2
- MYO16 | c.512A>G p.E171G | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1165194262; called by muse, mutect2, varscan2
- NBEA | c.5939G>A p.R1980H | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775542889, COSV59819890; called by muse, mutect2, varscan2
- PAPPA2 | c.4268G>T p.C1423F | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62789989; called by muse, mutect2, varscan2
- PARP14 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 58/282 reads (21%) | catalogued as COSV71735178; called by muse, mutect2, varscan2
- PCDH9 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1478576410; called by muse, mutect2, varscan2
- PCDHA6 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 232/815 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as rs1381710258, COSV65343822; called by muse, mutect2, varscan2
- PELI1 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 110/381 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1042843601; called by muse, mutect2, varscan2
- PLEKHH1 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs769942430; called by muse, mutect2, varscan2
- PPP1R3C | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 119/386 reads (31%) | catalogued as rs765361143; called by muse, mutect2, varscan2
- PRSS37 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 159/396 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs146733171; called by muse, mutect2, varscan2
- PSG3 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs369614691; called by muse, mutect2, varscan2
- RGPD4 | c.3070G>T p.D1024Y | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61746632, COSV61750165; called by muse, mutect2
- RIMBP3 | c.3407G>C p.C1136S | Missense Mutation (SNP) | VAF 130/983 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs751257526; called by muse, mutect2, varscan2
- SIGLEC6 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.041); catalogued as rs748993718, COSV58435362; called by muse, mutect2, varscan2
- SPEG | c.4759G>A p.G1587R | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs200114716; called by muse, mutect2, varscan2
- SPTA1 | c.7202G>A p.R2401Q | Missense Mutation (SNP) | VAF 94/361 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs746623140, COSV63523825; called by muse, mutect2, varscan2
- TP53 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs730882003, COSV52761693, COSV52809012, COSV52965683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRANK1 | c.4868G>A p.G1623D | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100082982; called by muse, mutect2, varscan2
- WDTC1 | c.1505G>A p.R502H (on ENST00000319394 / NM_001276252.2; = p.R501H on NM_015023.5) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as rs188048592; called by muse, mutect2, varscan2
- ZNF224 | c.1149G>A p.W383* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV61242422; called by muse, mutect2, varscan2
- CCER1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CNTNAP4 | c.2792G>C p.C931S | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DYNC1I1 | c.762C>A p.D254E | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- HMCN1 | c.9321G>C p.E3107D | Missense Mutation (SNP) | VAF 13/429 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.289); called by muse, mutect2
- HUWE1 | c.9937G>A p.E3313K | Missense Mutation (SNP) | VAF 26/447 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.114); called by muse, mutect2
- KCNG2 | c.1084T>C p.W362R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KHDC4 | c.1240del p.V414Cfs*73 | Frame Shift Del (DEL) | VAF 29/133 reads (22%) | called by mutect2, pindel, varscan2
- KIAA1958 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- MACF1 | c.3938C>G p.S1313W | Missense Mutation (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- MUC4 | c.9830del p.D3277Afs*982 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, varscan2
- MUC4 | c.8150del p.D2717Afs*287 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- NHSL2 | c.575G>T p.S192I (on ENST00000510661; = p.S558I on NM_001013627.2) | Missense Mutation (SNP) | VAF 115/207 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5M3 | c.595A>C p.I199L | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCDH9 | c.2887G>T p.V963L | Missense Mutation (SNP) | VAF 94/447 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PPT2 | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.072); called by muse, mutect2
- PRKCH | c.961-2A>C p.X321_splice | Splice Site (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- RBM5 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- STS | c.841T>C p.Y281H | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SYNE1 | c.2725C>A p.Q909K (on ENST00000367255 / NM_182961.4; = p.Q916K on NM_033071.3) | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TKTL1 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 79/213 reads (37%) | called by mutect2, pindel, varscan2
- ZNF41 | c.625A>C p.S209R | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- CCDC69 | c.708G>T p.L236= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- CNTNAP1 | c.1074G>A p.P358= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as COSV52850458; called by muse, mutect2, varscan2
- COTL1 | c.282C>T p.T94= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs201555655, COSV52290746, COSV99297235; called by muse, mutect2, varscan2
- DEFB110 | c.96C>T p.C32= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs780790692, COSV67018487; called by muse, mutect2, varscan2
- DIS3L | c.951C>T p.D317= (on ENST00000319212 / NM_001143688.3; = p.D234= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 47/77 reads (61%) | catalogued as rs776180747, COSV59910834; called by muse, mutect2, varscan2
- GJD4 | c.732C>T p.G244= | Silent (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- GPR50 | c.1029C>T p.R343= | Silent (SNP) | VAF 18/307 reads (6%) | catalogued as rs764002449; called by muse, mutect2
- IQGAP3 | c.1554C>T p.T518= | Silent (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- KCNT1 | c.2637C>T p.D879= (on ENST00000488444; = p.D898= on NM_020822.3) | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as rs369904278; ClinVar: likely benign; called by muse, mutect2, varscan2
- LACTB | c.519T>C p.A173= | Silent (SNP) | VAF 51/79 reads (65%) | called by muse, mutect2, varscan2
- MYLK | c.1062G>A p.P354= | Silent (SNP) | VAF 128/594 reads (22%) | catalogued as rs149571440; called by muse, mutect2, varscan2
- PCDHGA2 | c.1386C>T p.P462= | Silent (SNP) | VAF 95/375 reads (25%) | catalogued as rs765686553; called by muse, mutect2, varscan2
- PGM1 | c.1530C>T p.A510= | Silent (SNP) | VAF 109/375 reads (29%) | catalogued as rs554475249; called by muse, mutect2, varscan2
- PRR23B | c.525C>T p.A175= | Silent (SNP) | VAF 68/278 reads (24%) | catalogued as rs1434707319, COSV61494114; called by muse, mutect2, varscan2
- PTCHD3 | c.486C>T p.D162= | Silent (SNP) | VAF 81/285 reads (28%) | catalogued as rs140783092; called by muse, mutect2, varscan2
- SLC6A17 | c.693C>T p.L231= | Silent (SNP) | VAF 52/193 reads (27%) | called by muse, mutect2, varscan2
- SNAI2 | c.438T>C p.H146= | Silent (SNP) | VAF 22/544 reads (4%) | called by muse, mutect2
- SOX6 | c.912C>G p.P304= | Silent (SNP) | VAF 211/465 reads (45%) | catalogued as rs772358464, COSV100323421, COSV57035743; called by muse, mutect2, varscan2
- TRIM49 | c.75G>A p.P25= | Silent (SNP) | VAF 66/262 reads (25%) | catalogued as rs754735839, COSV100316006, COSV61671707; called by muse, mutect2, varscan2
- ABCC13 | n.3430C>T | RNA (SNP) | VAF 5/20 reads (25%) | catalogued as rs1413136214; called by muse, mutect2, varscan2
- AC079612.1 | n.398G>A | RNA (SNP) | VAF 89/338 reads (26%) | catalogued as rs752853909; called by muse, mutect2, varscan2
- CARD9 | c.*320G>A | 3'UTR (SNP) | VAF 22/104 reads (21%) | catalogued as rs1394170375; called by muse, mutect2
- GPHN | c.*524C>T | 3'UTR (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- HTR3A | c.*522G>A | 3'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- LMO7 | c.*16G>A | 3'UTR (SNP) | VAF 59/130 reads (45%) | catalogued as rs1263825492, COSV58547941; called by muse, mutect2, varscan2
- NKAIN4 | c.*10C>G | 3'UTR (SNP) | VAF 42/280 reads (15%) | called by muse, mutect2, varscan2
- TAF8 | chr6:42048648 C>T | 5'Flank (SNP) | VAF 25/99 reads (25%) | catalogued as COSV65897202; called by muse, mutect2, varscan2
